Gene-level copy-number profile of tumor specimen TARGET-40-PAMHLF-01A from TARGET case TARGET-40-PAMHLF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.9 years (3,233 days).
Specimen TARGET-40-PAMHLF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.401c5832-fd22-5a6f-94e3-fb074804c86a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMHLF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 407 have no estimate.
https://portal.gdc.cancer.gov/files/518bbc22-f4a9-4c89-97f4-b9337b530101

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 4,022; copy number 2: 15,319; copy number 3: 21,964; copy number 4: 14,133; copy number 5: 2,853; copy number 6: 603; copy number 7: 461; copy number 8: 122; copy number 9: 191; copy number 10: 255; copy number 11: 8; copy number 12: 206; copy number 13: 16; copy number 14: 33.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:113,738,106–113,776,837, 1 gene (within-gene range 0–2): AC093240.1.
- chr7:147,080,934–147,378,121, 4 genes: CNTNAP2-AS1, DUTP3, RANP2, MIR548F4.
- chr19:28,435,388–29,093,031, 16 genes (within-gene range 0–9): AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1.
- chr19:29,268,976–29,298,576, 1 gene: AC007786.4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,233 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:80,534,978–81,252,096, 7 genes, copy number 7 (within-gene range 4–7): AL136234.1, LINC01781, MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247.
- chr1:81,426,456–81,557,832, 5 genes, copy number 7: HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8.
- chr1:84,076,331–87,371,683, 68 genes, copy number 7 (broad region; genes not listed).
- chr1:143,541,768–148,263,632, 156 genes, copy number 10–12 (broad region; genes not listed).
- chr1:148,290,889–148,519,604, 1 gene, copy number 10 (within-gene range 4–10): LINC01138.
- chr1:148,362,370–153,070,840, 231 genes, copy number 7–14 (broad region; genes not listed).
- chr1:154,155,304–154,469,450, 20 genes, copy number 9 (within-gene range 1–9): TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1.
- chr1:156,934,840–157,112,412, 6 genes, copy number 8–13 (within-gene range 4–13): ARHGEF11, MIR765, RN7SL612P, SMU1P1, KRT8P45, ETV3L.
- chr1:157,232,231–157,237,136, 1 gene, copy number 7: AL138900.1.
- chr3:103,159,960–103,630,912, 5 genes, copy number 7: RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1, TUBBP11.
- chr4:56,907,876–57,495,844, 13 genes, copy number 7: REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1.
- chr6:111,660,332–111,909,420, 2 genes, copy number 9: FYN, LINC02527.
- chr6:112,107,931–112,254,939, 4 genes, copy number 10 (within-gene range 2–10): LAMA4, Z99289.1, RNU6-1226P, Z99289.2.
- chr6:116,529,013–117,573,571, 20 genes, copy number 9 (within-gene range 2–9): CALHM4, RWDD1, RSPH4A, ZUP1, KPNA5, FAM162B, GPRC6A, RFX6, RPS29P13, RNA5SP214, Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1, DCBLD1, RNU6-253P.
- chr8:76,491,200–77,537,290, 10 genes, copy number 10 (within-gene range 4–10): ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:103,500,696–104,256,094, 1 gene, copy number 7 (within-gene range 6–7): RIMS2.
- chr8:103,768,281–103,769,029, 1 gene, copy number 7: AC090686.1.
- chr8:104,339,087–104,356,689, 1 gene, copy number 7: DCSTAMP.
- chr8:108,443,601–111,757,710, 35 genes, copy number 7–11 (within-gene range 5–11): EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1.
- chr12:66,767–1,504,424, 30 genes, copy number 7–8 (within-gene range 4–8): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942.
- chr12:2,812,622–4,445,614, 41 genes, copy number 7–10 (within-gene range 5–10): ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6.
- chr12:5,432,108–5,946,232, 3 genes, copy number 7: NTF3, ANO2, AC137627.1.
- chr12:14,169,746–19,376,400, 77 genes, copy number 9–10 (broad region; genes not listed).
- chr12:20,361,732–20,753,386, 5 genes, copy number 8: AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1.
- chr12:25,959,029–26,079,892, 1 gene, copy number 8 (within-gene range 4–8): RASSF8.
- chr12:28,133,249–28,581,511, 1 gene, copy number 8 (within-gene range 5–8): CCDC91.
- chr12:28,319,335–34,249,958, 123 genes, copy number 7–13 (broad region; genes not listed).
- chr14:23,272,422–27,845,286, 119 genes, copy number 7–8 (broad region; genes not listed).
- chr14:56,813,183–57,152,177, 1 gene, copy number 8 (within-gene range 3–8): OTX2-AS1.
- chr14:56,951,008–57,298,742, 7 genes, copy number 8 (within-gene range 3–8): AL137100.3, RPL3P3, AL137100.1, AL137100.2, AL391152.1, EXOC5, AP5M1.
- chr17:16,191,832–16,382,745, 6 genes, copy number 9: RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3.
- chr19:21,719,801–23,147,221, 72 genes, copy number 7–12 (broad region; genes not listed).
- chr19:28,294,093–28,429,490, 4 genes, copy number 9: AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:29,698,886–31,427,302, 27 genes, copy number 12: C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1.
- chr19:34,533,427–36,105,108, 119 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr19:36,604,817–36,831,596, 9 genes, copy number 10 (within-gene range 2–10): ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1.
- chr21:18,686,090–18,686,164, 1 gene, copy number 7: MIR548X.

Autosomal genes at a single copy (total copy number 1): 2,557. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
